TCGA case TCGA-X6-A8C2 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: University of Iowa. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/90bc0f31-0ec2-4ceb-ad99-6be8f8b19180

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 56 years; Vital status: Alive.

Diagnoses (5)
1. Undifferentiated sarcoma (the primary disease): ICD-O-3 morphology code: 8805/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 56.1 years (20,507 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 3.1.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 3.1; Tumor length measurement: 5; Tumor width measurement: 3.5.
   Pathology details: Measurement type: Pathologic; Tumor burden: 5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2.2; Tumor length measurement: 3.1; Tumor width measurement: 2.8.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
2. Subsequent primary of the lung (histology not recorded by GDC). Age at diagnosis: 56.2 years (20,514 days); Days to diagnosis: 7 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Tumor burden: 0.8.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.3.
   Pathology details: Measurement type: Radiologic; Tumor burden: 0.5.
   Pathology details: Additional pathology findings: Well Differentiated.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.7; Tumor length measurement: 0.8; Tumor width measurement: 0.7.
3. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 57.2 years (20,885 days); Days to diagnosis: 378 days (1.0 years); Prior treatment: Yes.
   Pathology details: Measurement type: Pathologic; Tumor burden: 0.7.
   Pathology details: Additional pathology findings: Well Differentiated.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 0.6; Tumor length measurement: 0.7; Tumor width measurement: 0.7.
   Pathology details: Measurement type: Radiologic; Tumor burden: 0.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.5.
4. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 57.4 years (20,983 days); Days to diagnosis: 476 days (1.3 years); Prior treatment: Yes.
5. Metastasis of diagnosis 1 (Undifferentiated sarcoma), site: Lung, NOS. Age at diagnosis: 57.7 years (21,088 days); Days to diagnosis: 581 days (1.6 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Tumor burden: 4.5.

Follow-up (7 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 1.
- Days to follow up: 7 days; Discontiguous lesion count: 1.
- Day 378 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 378 days (1.0 years); Discontiguous lesion count: 1.
- Day 476 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 476 days (1.3 years).
- Day 581 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 581 days (1.6 years); Discontiguous lesion count: 2.
- Days to follow up: 782 days (2.1 years); Disease response: With Tumor.
- Days to follow up: 1,070 days (2.9 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-X6-A8C2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-X6-A8C2-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-X6-A8C2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-X6-A8C2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Undifferentiated Pleomorphic Sarcoma (UPS); Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No; Discontinuous lesions count: 1; Tumor burden pathologic: 5.0; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Lower leg/calf.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 5.0.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 677; Pharmaceutical therapy drug name: Doxorubicin; Pharmaceutical treatment ongoing indicator: Yes.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Radiation treatment 1: Days from index date to radiation therapy started: 74; Days from index date to radiation therapy ended: 120; Radiation therapy type: External; Radiation total dose: 6600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 33; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Complete Response.
- Radiation treatment 2: Days from index date to radiation therapy started: 660; Days from index date to radiation therapy ended: 671; Radiation therapy type: External; Radiation total dose: 30; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 10; Radiation therapy site: Distant Recurrence; Radiation therapy ongoing indicator: No; Treatment best response: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,070 days; disease-specific survival: no event (censored), 1,070 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 7 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-X6-A8C2-01A-11D-A36I-01): tumor purity 0.79, ploidy 2.96, whole-genome doublings 1.
